Gene-level copy-number profile of tumor specimen HCM-CSHL-0076-C25-01A from HCMI case HCM-CSHL-0076-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 74.8 years (27,308 days).
Specimen HCM-CSHL-0076-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ee488734-7583-4c2f-9e19-c512fc5918b5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0076-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/29df6b06-a052-4632-b040-59b678a3a493

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 595; copy number 1: 10,431; copy number 2: 41,799; copy number 3: 3,238; copy number 4: 1,852; copy number 5: 159; copy number 6: 52; copy number 9: 27; copy number 10: 203; copy number 11: 1; copy number 12: 10; copy number 13: 28; copy number 25: 5.

Homozygous deletions (total copy number 0; autosomes only): 595 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:109,334,713–109,409,974, 1 gene: PJA2.
- chr9:20,999,509–23,956,444, 68 genes (broad region; genes not listed).
- chr12:3,077,355–4,276,252, 23 genes (within-gene range 0–4): TSPAN9, Metazoa_SRP, TSPAN9-IT1, AC005912.2, AC005912.1, AC005865.1, LINC02827, LINC02417, PRMT8, AC005908.2, AC005908.1, THCAT155, CRACR2A, AC005831.1, RNU6-174P, AC006207.1, PARP11, OTUD4P1, PARP11-AS1, AC084375.1, HSPA8P5, AC007207.1, CCND2-AS1.
- chr18:46,756,487–80,247,514, 503 genes (within-gene range 0–3) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 485 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:220,621–1,495,933, 21 genes, copy number 5–9: SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2.
- chr12:1,660,315–1,788,674, 5 genes, copy number 9: MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14.
- chr12:2,695,765–3,072,145, 20 genes, copy number 5–12 (within-gene range 4–12): ITFG2-AS1, LINC02371, IQSEC3P1, AC092471.1, RPL23AP14, CBX3P4, FKBP4, ITFG2-AS1, AC005841.1, ITFG2, NRIP2, TEX52, FOXM1, RHNO1, TULP3, AC005911.1, RNU6-1315P, TEAD4, AC125807.2, AC125807.1.
- chr12:6,270,168–9,995,694, 216 genes, copy number 5–10 (within-gene range 4–10) (broad region; genes not listed).
- chr12:11,541,395–11,590,369, 3 genes, copy number 12: AC007450.1, RNU7-60P, LINC01252.
- chr12:12,049,844–12,696,207, 21 genes, copy number 13: BCL2L14, PTMAP9, MIR1244-4, LRP6, AC007537.1, RNU6-545P, AC007621.3, RNU6-318P, MANSC1, RPL23AP66, LOH12CR2, BORCS5, AC007619.2, DUSP16, AC007619.1, AC092824.1, CREBL2, RPL21P136, AC008115.4, GPR19, AC008115.2.
- chr12:13,371,089–13,982,002, 8 genes, copy number 6: LINC01559, GRIN2B, RNA5SP353, RNU6-590P, AC007527.1, AC007527.2, AC007535.1, RN7SKP162.
- chr12:15,620,134–15,903,478, 5 genes, copy number 9: EPS8, RNU6-251P, AC073651.1, AC073651.2, STRAP.
- chr12:16,188,485–16,788,375, 9 genes, copy number 5: SLC15A5, MGST1, SUPT16HP1, AC007528.1, AC007552.1, LMO3, AC007552.2, AC007529.2, AC007529.1.
- chr12:18,080,869–18,320,107, 1 gene, copy number 5 (within-gene range 4–5): RERGL.
- chr12:19,724,435–20,098,868, 4 genes, copy number 6–10: RNU1-146P, AC024901.1, TCP1P3, LINC02398.
- chr12:22,409,237–27,824,382, 99 genes, copy number 5–25 (within-gene range 1–25) (broad region; genes not listed).
- chr12:30,861,921–32,993,754, 73 genes, copy number 5–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,431. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
